Somatic mutation profile of tumor specimen TCGA-FK-A3S3-01A (aliquot TCGA-FK-A3S3-01A-11D-A22D-08) from TCGA case TCGA-FK-A3S3, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 43.4 years (15,853 days).
Specimen TCGA-FK-A3S3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5317456-b550-4ba6-91d1-f57c8ba99808.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FK-A3S3-10A (Blood Derived Normal), aliquot TCGA-FK-A3S3-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bc2036c-3b9d-462c-a428-987231af5e79

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV66581264; called by muse, mutect2
- NCK1 | c.82A>G p.R28G | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56638837; called by muse, mutect2, varscan2
- SCAF11 | c.910A>T p.T304S | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV65478093; called by muse, mutect2
- TMC1 | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV52780900; called by muse, mutect2, varscan2
- EPRS1 | c.3571_3575del p.D1191Ifs*6 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | called by mutect2, pindel, varscan2
- ANKRD26 | c.2037G>A p.Q679= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV65773982, COSV65776981; called by muse, mutect2
- IL13 | c.372G>A p.E124= | Silent (SNP) | VAF 4/76 reads (5%) | catalogued as COSV58734452; called by muse, mutect2
- MYO5C | c.3204C>G p.V1068= | Silent (SNP) | VAF 89/286 reads (31%) | catalogued as COSV55909859; called by muse, mutect2, varscan2
